Somatic mutation profile of tumor specimen 74a45e5a-a35a-4c60-a4b4-f3f5ea (aliquot 74a45e5a-a35a-4c60-a4b4-f3f5ea_D6) from CPTAC case 17OV029, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary.
Specimen 74a45e5a-a35a-4c60-a4b4-f3f5ea: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aef9924c-aa29-4085-b8e0-4d5f10e104f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 18c969bc-5783-4667-a9cf-30149e (Blood Derived Normal), aliquot 18c969bc-5783-4667-a9cf-30149e_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/902b3b45-cc06-470a-b233-703fafed0edc

The open-access MAF lists 64 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Intron 7, RNA 3, 5'UTR 2, 5'Flank 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS10 | c.2048G>A p.G683D | Missense Mutation (SNP) | VAF 92/123 reads (75%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs756069503; called by muse, mutect2, varscan2
- FBN3 | c.4205G>A p.C1402Y | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328652120; called by muse, mutect2, varscan2
- LPIN2 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV55242792; called by muse, mutect2, varscan2
- MUC17 | c.3896T>C p.L1299S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147387209, COSV60300304; called by mutect2, varscan2
- PRF1 | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as COSV64615188; called by muse, mutect2, varscan2
- RNF103 | c.132C>G p.S44R | Missense Mutation (SNP) | VAF 28/381 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs778641337; called by muse, mutect2
- SEMG2 | c.463T>A p.L155I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs377178712; called by mutect2, varscan2
- SPATC1 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as rs782061691, COSV66297990; called by muse, mutect2, varscan2
- STAG1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV99365920; called by muse, mutect2, varscan2
- TIPARP | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 181/407 reads (44%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV55814792; called by muse, mutect2, varscan2
- TM7SF3 | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100544993; called by muse, mutect2, varscan2
- TMPRSS3 | c.479C>G p.S160W | Missense Mutation (SNP) | VAF 64/762 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV52300540, COSV52304703; called by muse, mutect2
- ADAM12 | c.295T>A p.Y99N | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ANKRD31 | c.3530C>A p.S1177Y | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANKRD6 | c.423_424del p.N142Hfs*26 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- C1orf167 | c.2611C>G p.L871V | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by mutect2, varscan2
- CALHM4 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 117/140 reads (84%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CCDC174 | c.793A>G p.K265E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD2BP2 | c.150T>G p.D50E | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCN6 | c.2231T>G p.L744R | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CLIP2 | c.4C>G p.Q2E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CYP26C1 | c.786G>T p.E262D | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.013); called by mutect2, varscan2
- DDX47 | c.1121T>G p.L374R | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- DENND2C | c.1052C>G p.P351R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- EGFR | c.1000_1002del p.R334del | In Frame Del (DEL) | VAF 114/275 reads (41%) | called by mutect2, varscan2
- H3C8 | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HEPHL1 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNC1 | c.1335A>T p.L445F | Missense Mutation (SNP) | VAF 181/479 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC20 | c.376A>C p.N126H (on ENST00000355790 / NM_207119.3; = p.N76H on NM_018239.4) | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MRGPRG | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.223); called by mutect2, varscan2
- NCEH1 | c.654_680delinsAGAC p.Y218* (on ENST00000538775; = p.Y178* on NM_020792.6 and 1 other RefSeq transcript) | Nonsense Mutation (DEL) | VAF 18/26 reads (69%) | called by pindel, varscan2*
- NR4A3 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- NR4A3 | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- OOEP | c.363_370+28del p.X121_splice | Splice Site (DEL) | VAF 37/76 reads (49%) | called by mutect2, pindel, varscan2
- PIGZ | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- RHAG | c.1139-1G>C p.X380_splice | Splice Site (SNP) | VAF 86/239 reads (36%) | called by muse, mutect2, varscan2
- TEX101 | c.505C>T p.L169F (on ENST00000598265 / NM_001130011.3; = p.L187F on NM_031451.4) | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TIMMDC1 | c.342T>G p.H114Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TTN | c.27862G>C p.E9288Q (on ENST00000591111; = p.E8361Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/130 reads (36%) | PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CADPS | c.2586T>C p.N862= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- CCDC88C | c.75C>T p.G25= | Silent (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- EFL1 | c.1476T>C p.P492= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs576437556; called by mutect2, varscan2
- GNMT | c.135C>T p.Y45= | Silent (SNP) | VAF 79/198 reads (40%) | called by muse, mutect2, varscan2
- H2AC20 | c.39C>T p.A13= | Silent (SNP) | VAF 44/481 reads (9%) | catalogued as rs782555003, COSV58612459; called by muse, mutect2
- KLC1 | c.1329G>T p.G443= | Silent (SNP) | VAF 42/106 reads (40%) | called by mutect2, varscan2
- LAMA5 | c.10455C>T p.V3485= | Silent (SNP) | VAF 71/139 reads (51%) | catalogued as rs779863284, COSV53356409; called by muse, mutect2, varscan2
- MRFAP1L1 | c.351C>T p.L117= | Silent (SNP) | VAF 68/204 reads (33%) | catalogued as rs755768640, COSV57923194, COSV57923356; called by muse, mutect2, varscan2
- PRKAG2 | c.759A>T p.V253= | Silent (SNP) | VAF 70/198 reads (35%) | called by mutect2, varscan2
- STRN4 | c.741C>T p.N247= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as rs747015742, COSV54418033; called by muse, mutect2, varscan2
- ARHGAP6 | c.589-11184_589-11180del | Intron (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- ATE1 | c.942+1014G>T | Intron (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99817553; called by muse, mutect2, varscan2
- C10orf143 | c.69+4118C>T | Intron (SNP) | VAF 12/107 reads (11%) | called by mutect2, varscan2
- COL20A1 | c.3295-27G>A | Intron (SNP) | VAF 183/446 reads (41%) | catalogued as rs764192339, COSV58916447; called by muse, mutect2, varscan2
- DHRS9 | c.-399C>A | 5'UTR (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- FAM170A | c.-6G>T | 5'UTR (SNP) | VAF 72/81 reads (89%) | catalogued as COSV100088824; called by muse, mutect2, varscan2
- IDUA | chr4:986867 C>A | 5'Flank (SNP) | VAF 94/227 reads (41%) | called by muse, mutect2, varscan2
- KRBA2 | c.*9603A>T | 3'UTR (SNP) | VAF 45/64 reads (70%) | called by muse, mutect2, varscan2
- MYL7 | c.426+58C>T | Intron (SNP) | VAF 58/297 reads (20%) | catalogued as rs769842138; called by muse, mutect2, varscan2
- POM121L4P | n.448T>A | RNA (SNP) | VAF 12/128 reads (9%) | catalogued as rs1246374821; called by mutect2, varscan2
- SHOX2 | c.346+607C>G | Intron (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- SLC39A13 | c.735+173G>T | Intron (SNP) | VAF 178/412 reads (43%) | called by muse, mutect2, varscan2
- SSPOP | n.9498C>T | RNA (SNP) | VAF 160/362 reads (44%) | called by mutect2, varscan2
- XRCC5 | chr2:216109342 C>T | 5'Flank (SNP) | VAF 55/68 reads (81%) | catalogued as rs1041766962; called by muse, mutect2, varscan2
- ZNF971P | n.245G>A | RNA (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
